Somatic mutation profile of tumor specimen TCGA-HT-7884-01B (aliquot TCGA-HT-7884-01B-11D-2395-08) from TCGA case TCGA-HT-7884, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 44.6 years (16,280 days).
Specimen TCGA-HT-7884-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f288c8f1-f8a6-4825-9595-99fd4675df19.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7884-10A (Blood Derived Normal), aliquot TCGA-HT-7884-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d097eeb-df5a-4beb-aa9b-7bdb8d0e4045

The open-access MAF lists 32 somatic variants for this specimen: 27 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 22, Silent 5, Frame Shift Ins 2, In Frame Ins 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 49/110 reads (45%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 14/32 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, varscan2
- AVL9 | c.1201G>A p.A401T | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.795); catalogued as COSV59469771; called by muse, mutect2, varscan2
- CNDP1 | c.12A>T p.K4N | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.286); catalogued as COSV62595569; called by muse, mutect2
- FRMPD4 | c.3203T>C p.V1068A | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.11); catalogued as COSV66224371; called by muse, mutect2
- ITGB8 | c.1664A>G p.Y555C | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs752824831, COSV56015154; called by muse, mutect2
- LRRC37A3 | c.3821A>G p.D1274G | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV58537351; called by muse, mutect2, varscan2
- MAST3 | c.3830C>T p.P1277L | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs781277532, COSV53221218; called by muse, mutect2, varscan2
- NEUROG2 | c.486G>A p.W162* | Nonsense Mutation (SNP) | VAF 9/48 reads (19%) | catalogued as COSV57638343; called by muse, mutect2, varscan2
- PANK4 | c.1666G>A p.A556T | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.381); catalogued as COSV101022582; called by muse, mutect2
- PPP1R3F | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs781865197, COSV50020777; called by muse, mutect2, varscan2
- REG1A | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 64/343 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52071812; called by muse, mutect2, varscan2
- RTN4RL1 | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV58678699; called by muse, mutect2, varscan2
- SCN2A | c.1927A>G p.K643E | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV51857143; called by muse, mutect2, varscan2
- SERPINA7 | c.473T>C p.V158A | Missense Mutation (SNP) | VAF 15/311 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.132); catalogued as COSV59665841, COSV59667529; called by muse, mutect2
- SLC39A9 | c.328G>A p.V110I | Missense Mutation (SNP) | VAF 31/235 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0.011); catalogued as COSV50363730; called by muse, mutect2, varscan2
- SPINK5 | c.1462A>G p.K488E | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs758569792, COSV56263400; called by muse, mutect2
- SRRM2 | c.5801G>A p.R1934H | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.902); catalogued as rs780832298, COSV57081234; called by muse, mutect2, varscan2
- SYNE1 | c.9275A>G p.D3092G (on ENST00000367255 / NM_182961.4; = p.D3099G on NM_033071.3) | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55118280; called by muse, mutect2, varscan2
- TESPA1 | c.1151C>T p.S384L (on ENST00000316577 / NM_001098815.3; = p.S246L on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.057); catalogued as rs912527619, COSV100345254, COSV57261634; called by muse, mutect2, varscan2
- TP53 | c.861dup p.N288Efs*18 | Frame Shift Ins (INS) | VAF 26/82 reads (32%) | catalogued as COSV52922162; called by pindel, varscan2
- USH1G | c.420C>G p.F140L | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.78); PolyPhen benign (0.024); catalogued as COSV58883951; called by muse, mutect2
- YIPF1 | c.752G>C p.R251P | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50777057, COSV50780000; called by muse, mutect2, varscan2
- ZPR1 | c.479A>G p.D160G | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.597); catalogued as COSV57065374; called by muse, mutect2, varscan2
- ATRX | c.1074dup p.L359Tfs*3 | Frame Shift Ins (INS) | VAF 66/179 reads (37%) | called by mutect2, varscan2
- PLCH1 | c.1780del p.T594Pfs*2 (on ENST00000340059 / NM_001130960.2; = p.T606Pfs*2 on NM_014996.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 49/141 reads (35%) | called by mutect2, pindel, varscan2
- STXBP5L | c.143_144insCGC p.E48delinsDA | In Frame Ins (INS) | VAF 15/40 reads (38%) | called by mutect2, pindel, varscan2
- FKBP4 | c.1266G>A p.E422= | Silent (SNP) | VAF 35/239 reads (15%) | catalogued as rs1033322201, COSV50010176; called by muse, mutect2, varscan2
- PDHA2 | c.228A>G p.A76= | Silent (SNP) | VAF 8/146 reads (5%) | catalogued as COSV54777822, COSV54782377; called by muse, mutect2
- UBE3D | c.384C>G p.L128= | Silent (SNP) | VAF 53/140 reads (38%) | catalogued as COSV99389155; called by muse, mutect2, varscan2
- USP16 | c.1788T>C p.N596= | Silent (SNP) | VAF 25/160 reads (16%) | catalogued as COSV57628211; called by muse, mutect2, varscan2
- ZNF319 | c.1269G>A p.A423= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as rs750336166, COSV54624200; called by muse, mutect2, varscan2
